Somatic mutation profile of tumor specimen 0DAN6H from CCDI case PBBKBK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Choroid plexus carcinoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.3 years (1,214 days).
Specimen 0DAN6H: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 386d4ee4-297f-4d31-88bf-895416ac2c9a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DAN5Z (Solid Tissue; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45ac41a6-838b-49c4-b733-319826f554bf

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, 5'Flank 1, Silent 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM160A1 | c.2243G>A p.S748N | Missense Mutation (SNP) | VAF 392/451 reads (87%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1161865089; called by muse, mutect2, varscan2
- GPATCH8 | c.395T>A p.L132H | Missense Mutation (SNP) | VAF 24/820 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59194523; called by muse, mutect2
- KRTAP23-1 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 115/628 reads (18%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.988); catalogued as COSV61935620; called by muse, mutect2, varscan2
- LRIG3 | c.2944G>A p.E982K | Missense Mutation (SNP) | VAF 332/802 reads (41%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.031); catalogued as rs954036491, COSV57863327; called by muse, mutect2, varscan2
- MANEAL | c.886C>T p.P296S (on ENST00000373045 / NM_001113482.1; = p.P74S on NM_152496.2) | Missense Mutation (SNP) | VAF 26/614 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as COSV61116128; called by muse, mutect2
- COL11A2 | c.372T>G p.Y124* | Nonsense Mutation (SNP) | VAF 302/353 reads (86%) | called by muse, mutect2, varscan2
- GPC1 | c.376T>A p.F126I | Missense Mutation (SNP) | VAF 145/731 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NFAT5 | c.3008G>C p.S1003T | Missense Mutation (SNP) | VAF 278/444 reads (63%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OLIG1 | c.658C>A p.L220M | Missense Mutation (SNP) | VAF 78/173 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- PARP8 | c.2062A>G p.K688E | Missense Mutation (SNP) | VAF 145/483 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- RAC1 | c.4C>G p.Q2E | Missense Mutation (SNP) | VAF 11/329 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.056); called by muse, mutect2
- RANBP2 | c.2489T>G p.L830R | Missense Mutation (SNP) | VAF 138/438 reads (32%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.84); called by muse, mutect2
- STXBP5L | c.2140T>C p.F714L | Missense Mutation (SNP) | VAF 370/454 reads (81%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MANEAL | c.885G>C p.T295= (on ENST00000373045 / NM_001113482.1; = p.T73= on NM_152496.2) | Silent (SNP) | VAF 26/605 reads (4%) | called by muse, mutect2
- FBXO44 | chr1:11654422 C>T | 5'Flank (SNP) | VAF 73/167 reads (44%) | called by muse, mutect2, varscan2
- SYCP1 | c.1321-56T>C | Intron (SNP) | VAF 62/115 reads (54%) | called by muse, mutect2, varscan2
